TCGA case TCGA-DV-5568 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: NCI Urologic Oncology Branch. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/16559faa-8103-4973-a47d-3435443e8ec1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 26 years; Vital status: Alive.

Diagnoses (4)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 26.6 years (9,714 days); Year of diagnosis: 2009; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes.
   Pathology details: Consistent pathology review: Yes.
2. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Left; Classification of tumor: Prior primary; AJCC staging edition: 6th; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Synchronous primary of the kidney (histology not recorded by GDC). Laterality: Bilateral; AJCC staging edition: 6th.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Hemangioma, NOS: ICD-O-3 morphology code: 9120/0; Tissue or organ of origin: Eye, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab; Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 370 days (1.0 years); Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- Platelets: Normal.
- Hemoglobin: Low.
- Calcium: Low.
- Leukocytes: Elevated.
- Lactate Dehydrogenase: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DV-5568-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-DV-5568-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-DV-5568-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-DV-5568-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DV-5568-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: No.
- Follow-up form: Tumor status: With tumor.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy laterality: Both.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: Kidney Clear Cell Renal Carcinoma.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -973.
- Other malignancy form 3: Other malignancy anatomic site: Eye; Other malignancy histological type: Retinal Angioma.
- Other malignancy form 3, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form 3, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Avastin.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy L KIRC. No systemic chemotherapy or radiation. Prior malignancy of the eye treated with Avastin. Pt with synchronous bilateral KIRC.
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 370 days; disease-specific survival: no event (censored), 370 days; progression-free interval: no event (censored), 370 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-DV-5568-01): tumor purity 0.56, ploidy 2.02, whole-genome doublings 0 (call status: legacy_call).
